Somatic mutation profile of tumor specimen TCGA-OR-A5LF-01A (aliquot TCGA-OR-A5LF-01A-11D-A30A-10) from TCGA case TCGA-OR-A5LF, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 74.4 years (27,179 days).
Specimen TCGA-OR-A5LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10ce5354-7891-49b0-ade2-ee06dd657bdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LF-10A (Blood Derived Normal), aliquot TCGA-OR-A5LF-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f53a3d5-249b-429d-998e-f390d4a6de50

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 3, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.3734C>T p.T1245M | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs770749364, COSV65774423; called by muse, mutect2, varscan2
- C16orf90 | c.206G>A p.R69H (on ENST00000399645 / NM_001353385.2; = p.R60H on NM_001080524.2) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as rs756424414; called by mutect2, varscan2
- CTDSP2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755782534; called by muse, mutect2, varscan2
- GAS2L3 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57157901; called by muse, mutect2, varscan2
- H4C5 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs201304438, COSV100748095, COSV63486138; called by muse, varscan2
- NSDHL | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as rs781926585; called by muse, varscan2
- POLD2 | c.797A>G p.K266R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as rs1255105681; called by muse, mutect2, varscan2
- ATF7IP | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD8 | c.5286_5304dup p.A1769Rfs*19 (on ENST00000646647 / NM_001170629.2; = p.A1490Rfs*19 on NM_020920.4) | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- GTF3C1 | c.1006_1022del p.L336Efs*2 | Frame Shift Del (DEL) | VAF 35/203 reads (17%) | called by mutect2, pindel, varscan2
- NF1 | c.5908del p.R1970Efs*9 (on ENST00000358273 / NM_001042492.3; = p.R1949Efs*9 on NM_000267.3) | Frame Shift Del (DEL) | VAF 56/109 reads (51%) | called by mutect2, pindel, varscan2
- PIN4 | c.452T>C p.M151T (on ENST00000664196; = p.M126T on NM_006223.4) | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PRKCG | c.496del p.R166Gfs*10 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- WNK1 | c.1377C>A p.C459* | Nonsense Mutation (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- XDH | c.2801C>A p.T934N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- ZCCHC17 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF703 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KIAA2026 | c.1104C>G p.T368= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs1271452594; called by muse, mutect2, varscan2
- PYCARD | c.54G>A p.E18= | Silent (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- RECQL | c.1689T>G p.A563= | Silent (SNP) | VAF 56/128 reads (44%) | catalogued as COSV53709766; called by muse, mutect2, varscan2
- SMC1A | c.657T>C p.A219= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.1143T>C p.H381= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- TLE3 | c.1104G>A p.A368= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as rs1385438441; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2058G>A | Intron (SNP) | VAF 55/134 reads (41%) | called by muse, mutect2, varscan2
